Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8344, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8344-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

year old male with history of painless gross hematuria, US showing right renal mass.

Specimens Submitted:

1: SP: Kidney and adrenal, right; nephrectomy

2: SP: Lymph nodes, paracaval and interaortocaval; excision

DIAGNOSIS:

1. SP: Kidney and adrenal, right; nephrectomy

Tumor Type:

Renal cell carcinoma - Chromophobe type
eosinophilic variant

Tumor Size:

Greatest diameter is 8.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

No significant pathologic changes

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

Comment: Immunostains for CK7, CD10 and MIB-1 support the above interpretation.

2. SP: Lymph nodes, paracaval and interaortocaval; excision

Lymph Nodes:

Not involved

Number of nodes examined:15

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CK7	
	MIB-1 (Ki-67)	
	CD10	
	RECUT	
	RECUT	
	RECUT	
	NEG CONT	
	IMM RECUT	

Gross Description:

1). The specimen is received fresh labeled "right kidney and adrenal" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1005 g in total. The kidney measures 15 x 10.5 x 6.5 cm. The attached ureter measures 9.2 cm in length and 0.5 cm in diameter. The attached renal vein measures 1.1 cm in length and 1.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 5.5 x 0.8 x 0.5 cm. The kidney is inked black and bivalved to reveal a cortical, lobulated brown-tan mass measuring 8.5 x 8.5 x 5.5 cm located in the superior pole; at the center of the mass there is a white fibrous scar measuring 4.5 cm in greatest dimension. The mass does not appear to invade into the perirenal fat. The mass impinges on the pelvic system but does not appear to grossly involve it. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 1.5 cm in largest dimension and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
TRP -- tumor with renal pelvis
TPF - tumor with peri-renal fat
K -- representative sections kidney
AD -- adrenal gland

2). The specimen is received in formalin, labeled "Paracaval interaortocaval lymph nodes" and consists of multiple pink and red tan lymph nodes ranging in size from 0.2 to 1.9 cm which are entirely submitted

summary of sections:

LN-lymph nodes submitted:
BLN-bisected largest node

Summary of Sections:

Part 1: SP: Kidney and adrenal, right; nephrectomy

Source: NCI Genomic Data Commons file 7728ca38-2757-4e08-b5b2-43c5688c402b (TCGA-KL-8344.C4304EF6-2F5A-4AAB-88AD-8D5CC721A04E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).